CCDI case PBCJKZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d4f10654-4eb5-48b4-a1de-c488d7d45c96

Demographics
Sex at birth: male.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 9.3 years (3,399 days).

Biospecimens (3 samples)
- Sample 0DTGD1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTGDC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DTGDH: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
